TCGA case TCGA-36-2532 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: BC Cancer Agency. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/04abcf51-c52a-4e74-a5f4-4bc4fb444902

Demographics
Sex at birth: female; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 61.1 years (22,333 days); Year of diagnosis: 2007; Method of diagnosis: Excisional Biopsy; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Residual disease: R0; Days to last follow up: 897 days (2.5 years).
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: No macroscopic disease; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 140 days; Number of cycles: 6; Prescribed dose: 564; Prescribed dose units: mg; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 140 days; Number of cycles: 6; Treatment dose: 2,201 mg; Prescribed dose: 93; Prescribed dose units: mg; Route of administration: Intraperitoneal / Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 897 days (2.5 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-36-2532-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.7; Intermediate dimension: 0.9; Shortest dimension: 0.7.
  Slide TCGA-36-2532-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
  Slide TCGA-36-2532-01A-01-BS1: Section location: Bottom; Percent tumor cells: 92; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 5.
- Sample TCGA-36-2532-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Lymphovascular invasion indicator: Yes.
- Drug treatment 1, Route of administrations: Route of administration: IP.
- Drug treatment 2, Route of administrations: Route of administration: IP; Route of administration: IV.

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-36-2532-01A-01R-1048-01: Pairwise comparisons of expression results between platforms HT_HG-U133A and AgilentG4502A_07 suggests that results from this aliquot were from a different patient and therefore these data have been removed.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 897 days; disease-specific survival: no event (censored), 897 days; progression-free interval: no event (censored), 897 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-36-2532-01A-01D-1043-01): tumor purity 0.86, ploidy 1.91, whole-genome doublings 0.
